Gene-level copy-number profile of tumor specimen TCGA-57-1994-01A from TCGA case TCGA-57-1994, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; Age at diagnosis: 63.1 years (23,062 days).
Specimen TCGA-57-1994-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.61e9dfe5-0e48-498b-ab8d-075ed75a8bdc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-57-1994-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6b2de96e-df6d-4fa2-ac96-c07eaaba6d84

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 2,830; copy number 2: 9,065; copy number 3: 19,361; copy number 4: 16,239; copy number 5: 5,678; copy number 6: 2,028; copy number 7: 3,238; copy number 8: 581; copy number 9: 343; copy number 10: 166; copy number 12: 18; copy number 13: 4; copy number 14: 117; copy number 15: 13; copy number 17: 125.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-57-1994-01A-01D-0648-01): tumor purity 0.75, ploidy 3.29, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,605 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–154,548,147, 500 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr3:112,396,647–117,139,389, 80 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr3:117,672,154–169,663,775, 891 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr3:169,709,295–186,493,661, 309 genes, copy number 7–8 (broad region; genes not listed).
- chr4:67,417,305–75,902,571, 192 genes, copy number 7–14 (within-gene range 3–14) (broad region; genes not listed).
- chr5:58,198–25,324,386, 407 genes, copy number 9–10 (within-gene range 6–10) (broad region; genes not listed).
- chr5:31,400,497–45,895,970, 250 genes, copy number 7 (broad region; genes not listed).
- chr6:81,491,439–81,752,774, 1 gene, copy number 7 (within-gene range 6–7): TENT5A.
- chr6:81,622,200–94,194,658, 170 genes, copy number 7 (broad region; genes not listed).
- chr6:94,397,664–99,175,479, 37 genes, copy number 8–15: AL078595.3, AL078595.2, MTCYBP36, CYCSP17, MANEA-DT, MANEA, AL607077.1, AL034348.1, KRT18P50, FUT9, UFL1-AS1, RN7SL797P, UFL1, FHL5, RPS7P8, RNU4-70P, TYMSP1, AL355143.1, EEF1GP6, AL033379.1, GPR63, NDUFAF4, RN7SL509P, KLHL32, MMS22L, AL589740.1, AL080316.1, MIR2113, EIF4EBP2P3, AL590727.1, AL589826.1, AL589826.2, POU3F2, FBXL4, AL078603.1, MIR548AI, BDH2P1.
- chr8:40,519,565–42,207,709, 35 genes, copy number 7: AC010857.1, ZMAT4, AC048387.1, RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P, SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT.
- chr8:65,644,734–69,130,345, 56 genes, copy number 7 (within-gene range 6–7): MTFR1, AC055822.1, PDE7A, AC100812.1, DNAJC5B, AC084082.1, TRIM55, CRH, LINC00967, AC009879.4, RRS1-AS1, RRS1, AC009879.2, AC009879.3, ADHFE1, AC009879.1, VXN, RNU6-1324P, MYBL1, VCPIP1, Y_RNA, C8orf44-SGK3, C8orf44, SGK3, PTTG3P, MCMDC2, SNHG6, SNORD87, TCF24, PPP1R42, AC110998.1, COPS5, CSPP1, RNA5SP268, AC087359.1, ARFGEF1, AC021321.2, AC021321.1, AC011037.1, CPA6, NACAP10, AC022874.1, NDUFS5P6, PREX2, AC011853.2, AC011853.1, Y_RNA, RPL31P40, C8orf34-AS1, C8orf34, RPS15AP25, RNA5SP269, AC083967.1, LINC01592, RNU7-102P, AF201337.1.
- chr9:38,360,427–43,045,120, 139 genes, copy number 8 (broad region; genes not listed).
- chr10:19,048,801–24,547,848, 84 genes, copy number 7–8 (within-gene range 1–8) (broad region; genes not listed).
- chr10:36,089,086–38,783,108, 58 genes, copy number 8: AL355300.1, MTND5P17, MTND4P18, AL590730.1, AL590730.2, NAMPTP1, Y_RNA, AL390061.1, MKNK2P1, ARL6IP1P2, ANKRD30A, RNU6-811P, AL157387.1, LINC00993, RN7SL314P, Y_RNA, TMEM161BP1, VN1R53P, TACC1P1, MTND1P18, MTRNR2L7, AL132657.1, ZNF248, AL132657.2, ZNF33BP1, TLK2P2, AL135791.1, ZNF37CP, ZNF33CP, ZNF25, ZNF25-DT, Y_RNA, ZNF33A, RNU6-795P, AL161931.1, EIF3LP3, FXYD6P2, ZNF37A, AL117339.4, AL117339.3, AL117339.1, CCNYL4, AL133217.1, AL117339.2, HSD17B7P2, SEPTIN7P9, AL133216.2, RNU6-1118P, CICP9, AL133216.1, ABCD1P2, AL133173.2, PABPC1P12, SLC9B1P3, ACTR3BP5, CHEK2P5, AL133173.1, AL590623.1.
- chr12:66,767–39,619,803, 876 genes, copy number 7–8 (broad region; genes not listed).
- chr19:27,638,483–37,309,641, 321 genes, copy number 10–17 (broad region; genes not listed).
- chr20:87,250–6,780,246, 199 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,233. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
